Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3CN, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3CN-01A (Primary Tumor).

[page 1 of 2]
hw 10/15/11

Redacted ry Case gy Report

DOB:
Physician:

Sex: F

Received:

Pathologist:

Accession:

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) SKIN ANTERIOR NECK:
Intradermal nevus.
- (B) LEFT MIDJUGULAR LYMPH NODE:
One lymph node, no tumor present.
- (C) PRE-THYROID LYMPH NODE:
One lymph node, no tumor present.
- (D) THYROID AND PARATRACHEAL LYMPH NODES:
PAPILLARY CARCINOMA (1.5 CM DIAMETER) INVOLVING LEFT LOBE.
TUMOR FOCALLY EXTENDS TO INKED MARGIN OF RESECTION.
EXTRATHYROIDAL EXTENSION PRESENT.
No vascular/lymphatic invasion identified.
Adenomatous nodules of right lobe. (see comment)
Focal chronic lymphocytic thyroiditis.
Seven lymph nodes, no tumor present.
- (E) LEFT PARATHYROID TISSUE:
Parathyroid tissue, no tumor present.

1 CD-0-3
Carcinoma, papillary, thyroid
8260/3
Site: thyroid, NOS C73.9
hw 10/15/11

Entire report and diagnosis completed by:
Report released by:

COMMENT

In specimen D, the right lobe of the thyroid contains two adenomatous nodules which are 0.5 cm and 0.4 cm in greatest dimension.

GROSS DESCRIPTION

- (A) SKIN FROM THE ANTERIOR NECK - A strip of white skin (2.5 cm in length x 0.4 x 0.4 cm). No lesions are identified. Entire specimen is submitted in cassette A.
- (B) LEFT MIDJUGULAR LYMPH NODE - A single pink unremarkable lymph node (0.5 x 0.5 x 0.5 cm). The entire lymph node is submitted in cassette B. CC/kk
- (C) PRE-THYROID LYMPH NODE - A single pink unremarkable lymph node (0.4 x 0.4 x 0.4 cm). Entire lymph node is submitted in cassette C.
- (D) THYROID AND PARATRACHEAL LYMPH NODES - A bilobed thyroid and attached fibroadipose tissue with overall measurements of 6.0 x 5.5 x 1.5 cm. Grossly, the left lobe is slightly enlarged and contains a firm nodule. The nodule is 1.5 x 1.3 x 1.3 cm in diameter. The nodule is light tan and slightly firm and well demarcated from the surrounding normal thyroid tissue. The nodule abuts the anterior surgical margin. No other lesions are identified.
INK CODE: Black - external surface.
SECTION CODE: D1-D4, representative sections of the right lobe; D5-D9, nodule in left lobe; D10, multiple lymph nodes.
- (E) LEFT PARATHYROID TISSUE - A fragment of maroon-tan tissue (0.4 x 0.4 x 0.2 cm in greatest dimension), entirely submitted for frozen section in E.

*FS/DX: PARATHYROID TISSUE, NO TUMOR PRESENT.

[page 2 of 2]
9

History Case Pathology Report

DOB:
Physician:

Sex: F

Received:

Pathologist:

Accession:

Case type: Surgical History

CONSULTATION

SNOMED CODES

Source: NCI Genomic Data Commons file 619eaffb-d3bb-41d3-ad4e-835769155764 (TCGA-EL-A3CN.CF43F52C-E738-49CA-A3C5-33BC3E183867.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).